Somatic mutation profile of tumor specimen TCGA-AK-3444-01A (aliquot TCGA-AK-3444-01A-01D-0966-08) from TCGA case TCGA-AK-3444, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 80.8 years (29,497 days).
Specimen TCGA-AK-3444-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 906124fb-67a1-45ca-b7a4-b750256bd96b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AK-3444-10A (Blood Derived Normal), aliquot TCGA-AK-3444-10A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd348622-1435-4d04-8984-06439beb0502

The open-access MAF lists 106 somatic variants for this specimen: 79 protein-altering or splice-affecting, 23 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 23, Frame Shift Del 7, Nonsense Mutation 3, In Frame Del 3, Splice Site 2, Frame Shift Ins 2, Intron 2, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.194C>A p.S65* | Nonsense Mutation (SNP) | VAF 10/16 reads (63%) | hotspot (GDC flag); catalogued as rs5030826, CM941362, CM941363, CM941364, COSV56543026, COSV56543035, COSV56543220, COSV56562588; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.3292C>T p.Q1098* | Nonsense Mutation (SNP) | VAF 10/98 reads (10%) | catalogued as COSV61372190; called by muse, mutect2
- BACE2 | c.382A>T p.T128S | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1439528201; called by muse, mutect2, varscan2
- CFAP221 | c.1951G>T p.D651Y | Missense Mutation (SNP) | VAF 108/468 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV54654135, COSV99732337; called by muse, mutect2, varscan2
- CTAGE1 | c.1284dup p.A429Sfs*3 | Frame Shift Ins (INS) | VAF 36/143 reads (25%) | catalogued as rs756054046; called by mutect2, pindel, varscan2
- CX3CR1 | c.834del p.E279Rfs*10 | Frame Shift Del (DEL) | VAF 17/143 reads (12%) | catalogued as COSV100843329; called by mutect2, pindel, varscan2
- EHHADH | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.254); catalogued as rs1158697281, COSV51631804; called by muse, mutect2, varscan2
- ERBB4 | c.1778G>T p.C593F | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV53529587; called by muse, mutect2, varscan2
- GIMAP8 | c.1192G>C p.A398P | Missense Mutation (SNP) | VAF 82/332 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.22); catalogued as COSV56232964; called by muse, mutect2, varscan2
- GPR35 | c.785G>A p.S262N | Missense Mutation (SNP) | VAF 20/464 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV60578749; called by muse, mutect2
- HLF | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779590300, COSV56831389; called by muse, mutect2, varscan2
- KALRN | c.4724T>G p.I1575S | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99567440; called by muse, mutect2, varscan2
- LIPE | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs376903518; called by muse, mutect2
- LRP6 | c.4367G>A p.S1456N | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.347); catalogued as rs367658176; called by muse, mutect2
- MEGF8 | c.1822C>A p.L608I | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.341); catalogued as rs1381630142; called by muse, mutect2, varscan2
- MLC1 | c.312C>A p.N104K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.358); catalogued as rs763564142, COSV61116059; called by muse, mutect2, varscan2
- NID2 | c.4093G>A p.A1365T | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs201207693; called by muse, mutect2, varscan2
- NUDT19 | c.288C>A p.F96L | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV67959602; called by muse, mutect2, varscan2
- OPRL1 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as rs150300242, COSV100402214; called by muse, mutect2
- PCDHGA3 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.033); catalogued as COSV53930602; called by muse, mutect2, varscan2
- POU6F2 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 22/494 reads (4%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.994); catalogued as COSV68866982; called by muse, mutect2
- PZP | c.4075G>C p.D1359H | Missense Mutation (SNP) | VAF 86/227 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV54356689; called by muse, mutect2, varscan2
- RNASEH2A | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as CD150565; called by muse, mutect2, varscan2
- SAP130 | c.1048C>T p.H350Y | Missense Mutation (SNP) | VAF 59/228 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.225); catalogued as rs1477417985; called by muse, mutect2, varscan2
- SARDH | c.1160C>T p.T387M | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767736330; called by muse, mutect2, varscan2
- SOS1 | c.625A>C p.M209L | Missense Mutation (SNP) | VAF 28/266 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV101216948; called by muse, mutect2, varscan2
- TMIGD2 | c.385A>G p.T129A | Missense Mutation (SNP) | VAF 94/393 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV100010403, COSV56667447; called by muse, mutect2, varscan2
- UMODL1 | c.1520-1G>A p.X507_splice | Splice Site (SNP) | VAF 57/250 reads (23%) | catalogued as COSV61159573; called by muse, mutect2, varscan2
- WDR5 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62272626; called by muse, mutect2, varscan2
- ALG6 | c.1336_1341del p.S446_V447del | In Frame Del (DEL) | VAF 77/281 reads (27%) | called by mutect2, pindel, varscan2
- ANKMY1 | c.847T>C p.F283L | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID1B | c.4776del p.I1593Sfs*8 | Frame Shift Del (DEL) | VAF 108/362 reads (30%) | called by mutect2, pindel, varscan2
- B3GNT5 | c.197A>G p.H66R | Missense Mutation (SNP) | VAF 62/199 reads (31%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- CARS2 | c.618del p.K206Nfs*71 | Frame Shift Del (DEL) | VAF 57/185 reads (31%) | called by mutect2, pindel, varscan2
- COL12A1 | c.7367T>A p.F2456Y | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL15A1 | c.1192G>A p.V398I | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DCAKD | c.50T>C p.V17A | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- DLGAP3 | c.1183_1188del p.G395_S396del | In Frame Del (DEL) | VAF 72/216 reads (33%) | called by mutect2, pindel, varscan2
- DNAH5 | c.4177G>T p.G1393C | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- DYNC1H1 | c.13688T>G p.L4563W | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DYSF | c.6073T>A p.F2025I | Missense Mutation (SNP) | VAF 55/249 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ERICH6 | c.1096C>A p.H366N | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGFBP3 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.81); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FGFR4 | c.2336A>C p.D779A | Missense Mutation (SNP) | VAF 73/171 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FRMPD1 | c.329A>G p.D110G | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- GJD2 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- GNB1 | c.645A>C p.E215D | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR89B | c.1097T>A p.F366Y | Missense Mutation (SNP) | VAF 151/497 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- IDS | c.83C>G p.T28R | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- INCENP | c.1475T>C p.L492P | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KLF17 | c.1144G>T p.D382Y | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- KRT39 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- MCTP2 | c.2287A>G p.M763V | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NAV3 | c.512C>G p.A171G | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- NEB | c.13134dup p.K4379* | Frame Shift Ins (INS) | VAF 8/45 reads (18%) | called by mutect2, pindel, varscan2
- NOC3L | c.926del p.L309Wfs*16 | Frame Shift Del (DEL) | VAF 20/82 reads (24%) | called by mutect2, pindel, varscan2
- OR51E1 | c.946T>G p.S316A | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PHKA2 | c.625_636del p.L209_I212del | In Frame Del (DEL) | VAF 78/285 reads (27%) | called by mutect2, pindel, varscan2
- PIK3R4 | c.3640G>C p.D1214H | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- PMS2 | c.1081G>C p.G361R | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- POLE | c.3760del p.I1254Sfs*107 | Frame Shift Del (DEL) | VAF 94/330 reads (28%) | called by mutect2, pindel, varscan2
- POLR3B | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRRC2C | c.2521G>A p.D841N (on ENST00000367742; = p.D839N on NM_015172.4) | Missense Mutation (SNP) | VAF 88/321 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- PTPN22 | c.751-1G>T p.X251_splice | Splice Site (SNP) | VAF 22/72 reads (31%) | called by muse, mutect2, varscan2
- RALBP1 | c.331del p.V111Ffs*17 | Frame Shift Del (DEL) | VAF 42/156 reads (27%) | called by mutect2, pindel, varscan2
- SLC17A6 | c.376A>C p.M126L | Missense Mutation (SNP) | VAF 66/222 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SNX11 | c.596A>C p.E199A | Missense Mutation (SNP) | VAF 45/270 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SSUH2 | c.293G>T p.S98I | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- ST8SIA1 | c.903T>A p.N301K | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SYNJ2 | c.740C>A p.S247Y | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAGAP | c.1625del p.G542Vfs*30 | Frame Shift Del (DEL) | VAF 67/242 reads (28%) | called by mutect2, pindel, varscan2
- TGM5 | c.31G>T p.D11Y | Missense Mutation (SNP) | VAF 76/223 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM184C | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2
- TMEM61 | c.463G>T p.A155S | Missense Mutation (SNP) | VAF 75/208 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- TOP3A | c.1867A>T p.K623* | Nonsense Mutation (SNP) | VAF 104/293 reads (35%) | called by muse, mutect2, varscan2
- TTN | c.52648T>C p.F17550L (on ENST00000591111; = p.F10126L on NM_003319.4) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | PolyPhen benign (0.024); called by muse, mutect2, varscan2
- VSIG4 | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 108/313 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- WSCD1 | c.1550T>A p.L517Q | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBTB10 | c.1558G>A p.G520S | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- AP5Z1 | c.1935C>T p.S645= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs759141046; called by muse, mutect2, varscan2
- CADM1 | c.441G>A p.L147= | Silent (SNP) | VAF 61/187 reads (33%) | called by muse, mutect2, varscan2
- CDSN | c.513G>C p.G171= | Silent (SNP) | VAF 41/114 reads (36%) | called by muse, mutect2, varscan2
- CES2 | c.1200C>G p.P400= | Silent (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2, varscan2
- DGKI | c.2076G>T p.R692= | Silent (SNP) | VAF 22/344 reads (6%) | called by muse, mutect2
- E2F8 | c.198C>T p.L66= | Silent (SNP) | VAF 31/440 reads (7%) | catalogued as rs763610653; called by muse, mutect2
- FAM120B | c.612C>T p.V204= | Silent (SNP) | VAF 52/165 reads (32%) | called by muse, mutect2, varscan2
- FBXO9 | c.396T>C p.T132= | Silent (SNP) | VAF 45/142 reads (32%) | called by muse, mutect2, varscan2
- GDI2 | c.1002C>G p.V334= | Silent (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- HEPHL1 | c.411A>C p.S137= | Silent (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2, varscan2
- MYORG | c.1218G>A p.V406= | Silent (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- OGA | c.684G>A p.V228= | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as COSV63383265; called by muse, mutect2, varscan2
- OR2AG1 | c.717C>T p.V239= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as rs770528715; called by muse, mutect2, varscan2
- OR9G1 | c.567C>T p.G189= | Silent (SNP) | VAF 18/308 reads (6%) | catalogued as rs770442188, COSV56448164; called by muse, mutect2
- PFKP | c.978A>G p.G326= | Silent (SNP) | VAF 26/83 reads (31%) | called by muse, mutect2, varscan2
- PGLYRP4 | c.1101C>G p.T367= | Silent (SNP) | VAF 40/152 reads (26%) | called by muse, mutect2, varscan2
- PLXND1 | c.679C>T p.L227= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs755010441; called by muse, mutect2, varscan2
- SAP130 | c.1047T>C p.S349= | Silent (SNP) | VAF 60/227 reads (26%) | called by muse, mutect2, varscan2
- SPATA5 | c.591G>A p.G197= | Silent (SNP) | VAF 9/156 reads (6%) | called by muse, mutect2
- SPINT1 | c.36C>T p.L12= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs557336289; called by muse, mutect2, varscan2
- SRBD1 | c.6A>T p.S2= | Silent (SNP) | VAF 222/450 reads (49%) | called by muse, mutect2, varscan2
- STAG3 | c.2787G>A p.L929= | Silent (SNP) | VAF 33/159 reads (21%) | called by muse, mutect2, varscan2
- STAG3 | c.2788C>T p.L930= | Silent (SNP) | VAF 33/158 reads (21%) | called by muse, mutect2, varscan2
- AKR1D1 | c.690-173C>T | Intron (SNP) | VAF 7/33 reads (21%) | catalogued as rs539301673, COSV99652871; called by muse, mutect2, varscan2
- HERC2P3 | n.1914A>G | RNA (SNP) | VAF 28/77 reads (36%) | called by mutect2, varscan2
- PRR12 | chr19:49594891 C>A | 5'Flank (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- RGS3 | c.3081-333G>C | Intron (SNP) | VAF 132/368 reads (36%) | catalogued as rs765245767; called by muse, varscan2
